Gene-level copy-number profile of tumor specimen TARGET-40-PATJVI-01A from TARGET case TARGET-40-PATJVI, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.8 years (5,755 days).
Specimen TARGET-40-PATJVI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.b015cc6a-1c02-580d-89ce-e713d5a7ad09.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATJVI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 423 have no estimate.
https://portal.gdc.cancer.gov/files/b50fc173-3160-4be1-a1e9-be5601f0948e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 3,684; copy number 2: 26,642; copy number 3: 12,309; copy number 4: 12,455; copy number 5: 3,592; copy number 6: 1,159; copy number 7: 155; copy number 8: 111; copy number 9: 61; copy number 14: 3.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,824,213, 19 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr12:84,671,598–84,672,026, 1 gene: AC093027.1.
- chr17:7,754,320–7,754,976, 1 gene: RPL29P2.
- chr17:31,094,927–31,382,116, 2 genes (within-gene range 0–2): NF1, AC079915.1.
- chr20:64,255,695–64,313,132, 4 genes (within-gene range 0–3): PCMTD2, AL137028.2, CICP4, LINC00266-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,070 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:95,937,901–99,600,995, 34 genes, copy number 5 (within-gene range 4–5): LINC02790, RNU1-130P, LINC01787, AC092393.1, UBE2WP1, EEF1A1P11, RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270, PTBP2, DPYD, DPYD-AS1, DPYD-IT1, SEC63P1, RPL26P9, AC114878.1, DPYD-AS2, AC114878.2, MIR137HG, BX005019.1, MIR2682, MIR137, AC104453.1, NFU1P2, LINC01776, AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1, PLPPR4, AL365220.1, LINC01708.
- chr1:143,541,768–148,519,604, 166 genes, copy number 6 (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 4–9): AC244205.1.
- chr2:88,857,161–89,196,829, 33 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26.
- chr3:84,958,989–90,261,708, 42 genes, copy number 6–14 (within-gene range 3–14): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:134,026,665–134,327,977, 1 gene, copy number 5 (within-gene range 2–5): AC015631.1.
- chr4:134,196,333–134,545,648, 3 genes, copy number 5 (within-gene range 2–5): PABPC4L, PES1P1, LINC02462.
- chr7:79,768,028–80,226,181, 1 gene, copy number 5 (within-gene range 4–5): GNAI1.
- chr7:80,096,600–86,217,733, 44 genes, copy number 5: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr7:94,394,895–94,431,227, 1 gene, copy number 8: COL1A2.
- chr11:55,262,155–135,075,908, 2,173 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:15,001,787–30,321,617, 230 genes, copy number 5–6 (broad region; genes not listed).
- chr14:18,333,726–19,957,996, 83 genes, copy number 6 (broad region; genes not listed).
- chr14:25,647,304–106,824,147, 1,797 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr15:85,180,200–85,234,795, 1 gene, copy number 5 (within-gene range 3–5): AC044860.1.
- chr15:85,191,438–85,749,358, 10 genes, copy number 5 (within-gene range 3–5): CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3.
- chr15:100,846,604–101,933,350, 43 genes, copy number 5: AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr17:57,196,081–61,392,838, 145 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:61,865,367–62,320,189, 14 genes, copy number 5: INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1.
- chr17:63,009,556–73,092,712, 228 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr17:76,709,760–77,099,902, 18 genes, copy number 5: AC005837.4, JMJD6, AC005837.3, METTL23, AC005837.2, SRSF2, MFSD11, MIR636, RNU6-97P, LINC02080, AC016168.4, LINC00868, MGAT5B, AC016168.2, AC016168.1, AC016168.3, Metazoa_SRP, SNHG20.
- chr17:77,089,307–77,089,497, 2 genes, copy number 5: SCARNA16, MIR6516.

Autosomal genes at a single copy (total copy number 1): 3,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
